Somatic mutation profile of cancer-model specimen HCM-CSHL-0507-C20-85A (3D Organoid, passage 11; aliquot HCM-CSHL-0507-C20-85A-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0507-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 61.5 years (22,461 days).
Specimen HCM-CSHL-0507-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d88eccb7-aa2c-4e7b-8b6e-dc035d15fde3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0507-C20-11A (Solid Tissue Normal), aliquot HCM-CSHL-0507-C20-11A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ba5b6da-64cb-41db-ab2a-0392a6d2758f

The open-access MAF lists 153 somatic variants for this specimen: 107 protein-altering or splice-affecting, 43 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 43, Nonsense Mutation 10, Frame Shift Del 4, Intron 2, Frame Shift Ins 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 154/403 reads (38%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 90/320 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.745A>T p.R249W | Missense Mutation (SNP) | VAF 265/265 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.47098C>T p.R15700* (on ENST00000591111; = p.R8276* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 143/354 reads (40%) | catalogued as rs926741242, COSV59911426, COSV60201743; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALDH16A1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 240/541 reads (44%) | catalogued as rs758312798; called by muse, mutect2, varscan2
- APC | c.2287G>T p.E763* | Nonsense Mutation (SNP) | VAF 214/418 reads (51%) | catalogued as CM106354, COSV57350231; called by muse, varscan2
- APC | c.3080A>G p.Y1027C | Missense Mutation (SNP) | VAF 138/288 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs869312784, COSV57396420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AVP | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 54/872 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM087909; called by muse, mutect2
- CHST12 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 34/850 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs1486326455, COSV99324664; called by muse, mutect2
- CLCN2 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 118/370 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as rs1382714741; called by muse, mutect2, varscan2
- CNKSR2 | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 145/375 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54254556; called by muse, mutect2, varscan2
- CRHR1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 230/467 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766278959, COSV53276701; called by muse, mutect2, varscan2
- DIS3L2 | c.2575C>T p.R859W | Missense Mutation (SNP) | VAF 141/585 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs756617073, COSV56059243; called by muse, mutect2, varscan2
- EMID1 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 172/338 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs764653508; called by muse, mutect2, varscan2
- EPHA5 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 214/446 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.076); catalogued as rs773032839, COSV56634701; called by muse, mutect2, varscan2
- FZR1 | c.1211A>G p.N404S | Missense Mutation (SNP) | VAF 93/519 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs1357788894; called by muse, mutect2, varscan2
- KEL | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 333/692 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765595801, COSV100786964; called by muse, varscan2
- KIAA1755 | c.2990G>A p.R997H | Missense Mutation (SNP) | VAF 143/1284 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs747051689, COSV54073295; called by muse, mutect2, varscan2
- M6PR | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423572568; called by muse, mutect2
- MMP16 | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 135/294 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271222004, COSV54165455; called by muse, mutect2, varscan2
- NBEA | c.4846T>C p.S1616P | Missense Mutation (SNP) | VAF 15/394 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.91); catalogued as rs1354317809; called by muse, mutect2
- NEO1 | c.3352G>A p.V1118M | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs746965566, COSV56073893; called by muse, mutect2, varscan2
- NGFR | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 191/961 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as rs770527312; called by muse, mutect2, varscan2
- NLRP1 | c.4279C>T p.R1427W (on ENST00000572272 / NM_033004.4; = p.R1383W on NM_014922.5) | Missense Mutation (SNP) | VAF 151/275 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754014640, COSV52566950, COSV99335467; called by muse, mutect2, varscan2
- NLRP1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 307/307 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs971095282; called by muse, mutect2, varscan2
- NOMO1 | c.1843G>A p.G615R | Missense Mutation (SNP) | VAF 163/419 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405138543; called by muse, mutect2, varscan2
- NRBP2 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 291/603 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs539183961, COSV59918256; called by muse, mutect2, varscan2
- NTNG2 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 230/889 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.842); catalogued as rs759223913; called by muse, mutect2, varscan2
- NUP93 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 206/500 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771130377, COSV57428419; called by muse, mutect2, varscan2
- OBSL1 | c.4241G>A p.R1414H | Missense Mutation (SNP) | VAF 409/800 reads (51%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as rs762539444; called by muse, mutect2, varscan2
- OR5I1 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1332420849; called by muse, mutect2, varscan2
- PALB2 | c.3038T>C p.I1013T | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs775666266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKLR | c.1433G>C p.G478A | Missense Mutation (SNP) | VAF 73/410 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV61360645; called by muse, mutect2, varscan2
- PLXNA2 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 199/408 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1391420340; called by muse, mutect2, varscan2
- POU4F3 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 451/916 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV57942353; called by muse, mutect2, varscan2
- PPP6R1 | c.2428G>A p.G810R | Missense Mutation (SNP) | VAF 209/424 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs767658439, COSV58984111; called by muse, varscan2
- PRLH | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 168/413 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs766168277; called by muse, mutect2, varscan2
- PROKR2 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 278/547 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs776908572, COSV54087946; called by muse, mutect2, varscan2
- PTBP2 | c.40A>C p.T14P (on ENST00000426398 / NM_001300986.2; = p.T6P on NM_021190.4) | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.986); catalogued as rs1319096977; called by muse, mutect2, varscan2
- RGSL1 | c.3052G>A p.A1018T | Missense Mutation (SNP) | VAF 172/330 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1365640438; called by muse, mutect2
- RYR2 | c.3461G>A p.R1154H | Missense Mutation (SNP) | VAF 187/397 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as rs530867686, COSV63713805; called by muse, mutect2, varscan2
- SLITRK5 | c.2785C>T p.R929W | Missense Mutation (SNP) | VAF 258/726 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61522531; called by muse, varscan2
- SPACA9 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 260/582 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755256506, COSV100051376; called by muse, mutect2, varscan2
- THBS4 | c.2759G>T p.R920L | Missense Mutation (SNP) | VAF 136/578 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63467655; called by muse, mutect2, varscan2
- TSPAN7 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 332/332 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs776814898; called by muse, mutect2, varscan2
- UBASH3B | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 262/397 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs756434598, COSV52495623; called by muse, mutect2, varscan2
- WDR83OS | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 236/502 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs780185655, COSV99663915; called by muse, mutect2, varscan2
- ZIK1 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 89/520 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs140997650; called by muse, mutect2, varscan2
- ZNF723 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs554906814; called by muse, mutect2, varscan2
- AC021072.1 | c.234C>A p.C78* | Nonsense Mutation (SNP) | VAF 36/684 reads (5%) | called by muse, mutect2
- AKR1B15 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AL451007.3 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 105/932 reads (11%) | called by muse, mutect2, varscan2
- ANLN | c.1388C>T p.T463I | Missense Mutation (SNP) | VAF 114/261 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP45 | c.1575G>C p.Q525H | Missense Mutation (SNP) | VAF 349/683 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARMC4 | c.2781G>C p.L927F | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- C4orf50 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 106/412 reads (26%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.475); called by muse, varscan2
- CLIP4 | c.972del p.N324Kfs*26 | Frame Shift Del (DEL) | VAF 181/467 reads (39%) | called by mutect2, pindel, varscan2
- DGKG | c.158A>C p.D53A | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.097); called by muse, mutect2
- DOK6 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DPEP1 | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 66/706 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- DPP10 | c.1710A>C p.E570D | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2
- DTNBP1 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- EBF1 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 296/633 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- EFNB2 | c.390dup p.D131Rfs*17 | Frame Shift Ins (INS) | VAF 103/348 reads (30%) | called by mutect2, pindel, varscan2
- EGFL6 | c.1538A>T p.D513V | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- EIF6 | c.646T>C p.S216P | Missense Mutation (SNP) | VAF 132/1354 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2
- ELFN2 | c.2452C>T p.Q818* | Nonsense Mutation (SNP) | VAF 75/382 reads (20%) | called by muse, mutect2, varscan2
- FBXO11 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 336/694 reads (48%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.029); called by muse, varscan2
- FLG | c.7399G>A p.G2467R | Missense Mutation (SNP) | VAF 227/455 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GATA6 | c.1770C>A p.C590* | Nonsense Mutation (SNP) | VAF 106/245 reads (43%) | called by muse, mutect2, varscan2
- GPN2 | c.413_419del p.L138Pfs*86 | Frame Shift Del (DEL) | VAF 98/293 reads (33%) | called by mutect2, pindel, varscan2
- HEPHL1 | c.1821C>A p.S607R | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- IQCB1 | c.170A>G p.D57G | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.971); called by muse, mutect2
- IRX6 | c.1141A>T p.I381F | Missense Mutation (SNP) | VAF 26/878 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2
- KIAA1217 | c.1595G>C p.S532T | Missense Mutation (SNP) | VAF 108/539 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- KIAA1671 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 76/662 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- LPP | c.1765G>T p.G589W | Missense Mutation (SNP) | VAF 76/454 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRK1 | c.4734C>G p.C1578W | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MDC1 | c.5261G>T p.R1754M | Missense Mutation (SNP) | VAF 458/762 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MTHFD1L | c.2092G>C p.A698P | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MYBPH | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 278/569 reads (49%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYCBP2 | c.1483A>C p.I495L (on ENST00000357337; = p.I533L on NM_015057.5) | Missense Mutation (SNP) | VAF 47/408 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- N6AMT1 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- NBPF14 | c.4621T>C p.Y1541H | Missense Mutation (SNP) | VAF 137/368 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- NCAM2 | c.909C>A p.H303Q | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NPAS4 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 128/512 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- OR5C1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 39/698 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.026); called by muse, mutect2
- OSBPL6 | c.976del p.I326Yfs*55 | Frame Shift Del (DEL) | VAF 93/237 reads (39%) | called by mutect2, pindel, varscan2
- PTEN | c.733_744del p.Q245_P248del | In Frame Del (DEL) | VAF 111/116 reads (96%) | called by mutect2, pindel, varscan2
- RAD51B | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 100/215 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RALGDS | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 209/708 reads (30%) | called by muse, mutect2, varscan2
- SEPTIN10 | c.1056A>T p.R352S | Missense Mutation (SNP) | VAF 36/415 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- SESN1 | c.518A>T p.H173L (on ENST00000356644 / NM_001199933.1; = p.H232L on NM_014454.3) | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2
- SLC26A3 | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 107/462 reads (23%) | called by muse, mutect2, varscan2
- SLC34A3 | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 14/449 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- SLC7A6OS | c.870C>A p.Y290* | Nonsense Mutation (SNP) | VAF 138/580 reads (24%) | called by muse, mutect2, varscan2
- TDRD6 | c.2453G>T p.R818I | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TMEM248 | c.738_739del p.Y247Sfs*14 | Frame Shift Del (DEL) | VAF 128/396 reads (32%) | called by pindel, varscan2
- TMTC1 | c.1783C>T p.Q595* (on ENST00000539277 / NM_001193451.2; = p.Q487* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 11/211 reads (5%) | called by muse, mutect2
- TRIM66 | c.2177C>G p.A726G | Missense Mutation (SNP) | VAF 40/356 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRO | c.2327G>T p.S776I | Missense Mutation (SNP) | VAF 218/420 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UACA | c.3364A>G p.K1122E | Missense Mutation (SNP) | VAF 169/169 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UCKL1 | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 95/901 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UNC13C | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 181/181 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- WNK1 | c.1267T>A p.S423T | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- ZC3H13 | c.1295A>G p.E432G | Missense Mutation (SNP) | VAF 45/553 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.214); called by muse, mutect2
- ZNF471 | c.53A>T p.D18V | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACHE | c.1119G>C p.G373= | Silent (SNP) | VAF 74/745 reads (10%) | called by muse, mutect2, varscan2
- ADGRA1 | c.1068G>A p.L356= | Silent (SNP) | VAF 126/662 reads (19%) | catalogued as rs750331149; called by muse, mutect2, varscan2
- AHSG | c.630T>C p.A210= | Silent (SNP) | VAF 23/343 reads (7%) | catalogued as rs1172550077; called by muse, mutect2
- BEND4 | c.405C>T p.V135= | Silent (SNP) | VAF 85/567 reads (15%) | catalogued as rs1480731579; called by muse, mutect2, varscan2
- CA11 | c.420C>T p.R140= | Silent (SNP) | VAF 208/467 reads (45%) | called by muse, mutect2, varscan2
- CEACAM5 | c.567C>G p.P189= | Silent (SNP) | VAF 86/603 reads (14%) | called by muse, mutect2, varscan2
- CSMD1 | c.6831C>T p.F2277= (on ENST00000520002; = p.F2276= on NM_033225.6) | Silent (SNP) | VAF 124/247 reads (50%) | catalogued as rs371661443, COSV59378788; called by muse, mutect2, varscan2
- CSMD1 | c.2982C>T p.S994= (on ENST00000520002; = p.S993= on NM_033225.6) | Silent (SNP) | VAF 230/480 reads (48%) | catalogued as rs372606827; called by muse, mutect2, varscan2
- DZANK1 | c.2184C>G p.L728= (on ENST00000262547 / NM_001099407.1; = p.L535= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 130/508 reads (26%) | catalogued as rs761245722, COSV52757429; called by muse, mutect2, varscan2
- ETNK1 | c.351A>G p.L117= | Silent (SNP) | VAF 207/330 reads (63%) | catalogued as rs753384841, COSV56883592; called by muse, mutect2, varscan2
- FAT2 | c.9033T>C p.C3011= | Silent (SNP) | VAF 171/343 reads (50%) | catalogued as COSV99944440; called by muse, mutect2, varscan2
- FERMT3 | c.672G>A p.Q224= | Silent (SNP) | VAF 55/402 reads (14%) | called by muse, mutect2, varscan2
- FHOD3 | c.3825G>A p.K1275= (on ENST00000359247 / NM_001281739.3; = p.K1292= on NM_025135.5) | Silent (SNP) | VAF 10/187 reads (5%) | called by muse, mutect2
- FNBP1L | c.147G>A p.L49= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV99554748; called by muse, mutect2, varscan2
- FOXA1 | c.15G>T p.V5= | Silent (SNP) | VAF 75/325 reads (23%) | catalogued as COSV51645842; called by muse, mutect2, varscan2
- FRMPD2 | c.3009G>C p.V1003= | Silent (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- FUT11 | c.1221C>T p.A407= | Silent (SNP) | VAF 26/830 reads (3%) | catalogued as COSV59542140; called by muse, mutect2
- GALNT9 | c.507C>T p.R169= | Silent (SNP) | VAF 116/457 reads (25%) | catalogued as rs1555239877; called by muse, mutect2, varscan2
- GIT1 | c.1878A>G p.P626= | Silent (SNP) | VAF 135/487 reads (28%) | called by muse, mutect2, varscan2
- GNAS | c.1503C>T p.A501= | Silent (SNP) | VAF 1598/2163 reads (74%) | catalogued as rs1256423726; called by muse, mutect2, varscan2
- IL5RA | c.342T>A p.A114= | Silent (SNP) | VAF 21/342 reads (6%) | called by muse, mutect2
- IRX4 | c.873C>T p.A291= | Silent (SNP) | VAF 232/1101 reads (21%) | catalogued as rs1182368536; called by muse, mutect2, varscan2
- KANK1 | c.498A>G p.E166= | Silent (SNP) | VAF 67/644 reads (10%) | called by muse, mutect2, varscan2
- KRTAP27-1 | c.453C>T p.F151= | Silent (SNP) | VAF 46/453 reads (10%) | catalogued as rs781274963, COSV67000922; called by muse, mutect2, varscan2
- MN1 | c.3372G>A p.P1124= | Silent (SNP) | VAF 542/1118 reads (48%) | catalogued as rs766570466, COSV56559133; called by muse, mutect2, varscan2
- NCAPG | c.2478A>G p.V826= | Silent (SNP) | VAF 24/199 reads (12%) | called by muse, mutect2, varscan2
- NXPH2 | c.720T>C p.V240= | Silent (SNP) | VAF 89/343 reads (26%) | called by muse, mutect2, varscan2
- PHF11 | c.783C>T p.I261= | Silent (SNP) | VAF 66/272 reads (24%) | catalogued as rs746222741; called by muse, mutect2, varscan2
- PHF21B | c.111C>T p.S37= | Silent (SNP) | VAF 220/504 reads (44%) | called by muse, mutect2, varscan2
- PTPN13 | c.1204C>A p.R402= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV57404584; called by muse, mutect2, varscan2
- PTPRE | c.675A>G p.Q225= | Silent (SNP) | VAF 56/499 reads (11%) | called by muse, mutect2, varscan2
- QSOX2 | c.729C>T p.D243= | Silent (SNP) | VAF 247/540 reads (46%) | catalogued as rs572941682, COSV62393916; called by muse, mutect2, varscan2
- RCOR1 | c.1014G>A p.L338= | Silent (SNP) | VAF 84/168 reads (50%) | catalogued as COSV99217777; called by muse, mutect2, varscan2
- RETSAT | c.1395C>T p.P465= | Silent (SNP) | VAF 24/508 reads (5%) | called by muse, mutect2
- RSPH4A | c.447C>G p.T149= | Silent (SNP) | VAF 20/436 reads (5%) | called by muse, mutect2
- SMG1 | c.5814C>G p.S1938= | Silent (SNP) | VAF 65/330 reads (20%) | called by muse, mutect2, varscan2
- STIL | c.1965A>G p.A655= | Silent (SNP) | VAF 86/459 reads (19%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.2715C>T p.D905= | Silent (SNP) | VAF 87/298 reads (29%) | called by muse, mutect2, varscan2
- TOX3 | c.900A>G p.Q300= | Silent (SNP) | VAF 29/209 reads (14%) | called by muse, mutect2, varscan2
- VANGL2 | c.969T>C p.S323= | Silent (SNP) | VAF 209/451 reads (46%) | called by muse, mutect2, varscan2
- VWF | c.1008C>A p.L336= | Silent (SNP) | VAF 45/314 reads (14%) | catalogued as COSV54615425; called by muse, mutect2, varscan2
- XKR6 | c.1212C>T p.G404= | Silent (SNP) | VAF 293/590 reads (50%) | catalogued as rs139763869, COSV58654723; called by muse, mutect2, varscan2
- ZNF446 | c.720G>A p.P240= | Silent (SNP) | VAF 240/533 reads (45%) | catalogued as rs767849151, COSV59992221; called by muse, mutect2, varscan2
- COL6A5 | c.*185T>C | 3'UTR (SNP) | VAF 20/139 reads (14%) | called by muse, mutect2, varscan2
- CSMD2 | c.8312-7398G>A | Intron (SNP) | VAF 202/368 reads (55%) | catalogued as rs765912423; called by muse, mutect2, varscan2
- SH2B1 | c.1897+11C>A | Intron (SNP) | VAF 55/488 reads (11%) | catalogued as rs561521722; called by muse, mutect2, varscan2
